MMRF case MMRF_2153 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ca26ccc6-86ac-4683-9d65-6c88e0198883

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.0 years (28,845 days); ISS stage: II; Days to last known disease status: 535 days (1.5 years); Days to last follow up: 535 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 382 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 382 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 393 days (1.1 years); Days to treatment end: 584 days (1.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 1.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 92.3 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.65 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 7.4 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 10.2 mg/dL.
- Day 98 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.56 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 8.2 mmol/L.
- Day 192 (ECOG 1): M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.6 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 305 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.45 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 6.71 mmol/L.
- Day 262 (ECOG 2): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.7 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.07 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 6.82 mmol/L.
- Day 360 (ECOG 2): M Protein 0.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.52 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 445 (ECOG 2): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.17 mg/dL; Immunoglobulin G 7.02 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 5.07 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 123 µmol/L; Calcium 2.3 mmol/L; Albumin 33 g/L; Glucose 8.42 mmol/L.
- Day 535: M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.16 mg/dL; Immunoglobulin G 5.9 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.17 µg/mL; Lactate Dehydrogenase 1.58 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day 1: Weight: 48 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2153_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2153_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
